Somatic mutation profile of tumor specimen TCGA-06-1800-01A (aliquot TCGA-06-1800-01A-01W-0643-08) from TCGA case TCGA-06-1800, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.1 years (22,332 days).
Specimen TCGA-06-1800-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 853a2bfd-70df-4103-9e05-1ff087c135fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-1800-10A (Blood Derived Normal), aliquot TCGA-06-1800-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c21dda6d-51c2-46d7-89f5-016bd8a9d674

The open-access MAF lists 70 somatic variants for this specimen: 53 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 50, Silent 17, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F22 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs776275777, COSV54107182, COSV54109072; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNK9 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs121908332, CM083533, COSV57283374; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 122/211 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.721T>C p.S241P | Missense Mutation (SNP) | VAF 505/691 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520002, CD984149, CM942121, COSV52670786, COSV52675302, COSV53004514; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AAMP | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV99816471; called by muse, mutect2, varscan2
- ACSBG2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs139116689; called by muse, mutect2, varscan2
- ATP10B | c.4360C>T p.R1454* | Nonsense Mutation (SNP) | VAF 155/418 reads (37%) | catalogued as rs200376757, COSV100515622; called by muse, mutect2, varscan2
- C6orf89 | c.321G>A p.M107I (on ENST00000373685; = p.M114I on NM_152734.4) | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100769748; called by muse, mutect2
- CDH1 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 32/760 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as rs876659951, COSV99932397; ClinVar: uncertain significance; called by muse, mutect2
- CDKN1B | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.201); catalogued as rs770629019, COSV99964015; called by muse, varscan2
- CLCA1 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 141/316 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs778793374, COSV52328159; called by muse, mutect2, varscan2
- COL10A1 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV99684343; called by mutect2, varscan2
- CORIN | c.2268C>G p.N756K | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99904098; called by muse, mutect2, varscan2
- DCBLD2 | c.1406G>A p.S469N | Missense Mutation (SNP) | VAF 104/327 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100472774; called by muse, mutect2, varscan2
- DNAJC13 | c.22A>C p.K8Q | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV99607754; called by muse, mutect2, varscan2
- F5 | c.6535G>C p.E2179Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.122); catalogued as COSV100889188; called by muse, mutect2
- FBN2 | c.5587C>T p.R1863W | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1192632165, COSV52540689; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FPR2 | c.112G>T p.V38F | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100389365; called by muse, mutect2, varscan2
- GPHN | c.1714G>A p.G572R (on ENST00000315266 / NM_001377519.1; = p.G605R on NM_020806.5) | Missense Mutation (SNP) | VAF 337/605 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100017088; called by muse, mutect2, varscan2
- INPP5D | c.1253dup p.P419Sfs*27 (on ENST00000445964 / NM_001017915.3; = p.P418Sfs*27 on NM_005541.5) | Frame Shift Ins (INS) | VAF 12/108 reads (11%) | catalogued as rs759837481; called by mutect2, varscan2
- KRTAP3-3 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); catalogued as COSV101195960; called by muse, mutect2, varscan2
- LAD1 | c.369C>G p.S123R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV100943898, COSV100943981; called by muse, mutect2, varscan2
- MBD6 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100670650; called by muse, mutect2, varscan2
- MCHR2 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV99912442; called by muse, mutect2, varscan2
- ME1 | c.1390G>T p.G464C | Missense Mutation (SNP) | VAF 160/555 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs914491574, COSV100866610; called by muse, mutect2, varscan2
- MST1R | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs1171070291, COSV99619294; called by muse, mutect2, varscan2
- NRG2 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs138450353; called by muse, mutect2, varscan2
- NSUN3 | c.260A>T p.K87I | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV100113391; called by muse, mutect2, varscan2
- OR2M2 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 82/267 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs149761766; called by muse, mutect2, varscan2
- OTOP1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs200612216; called by muse, mutect2, varscan2
- PIGT | c.932C>A p.T311N | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV99649130; called by muse, mutect2, varscan2
- PLCB4 | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 106/340 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99596279; called by muse, mutect2, varscan2
- PYGL | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 70/1373 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV99368897; called by muse, mutect2
- RB1 | c.1960G>A p.V654M | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs483352690, CM034902, CM045967, CS050405, CS081965, CS083261, COSV57303318, COSV57309017, COSV57322012; ClinVar: conflicting interpretations of pathogenicity; called by muse, varscan2
- RFC5 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 398/1450 reads (27%) | catalogued as COSV99969961; called by muse, varscan2
- RFX4 | c.917G>A p.R306Q (on ENST00000392842 / NM_213594.3; = p.R212Q on NM_032491.6) | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.885); catalogued as rs760741666, COSV57572258; called by muse, mutect2, varscan2
- RGS4 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 132/323 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs779741194, COSV63357460; called by muse, mutect2, varscan2
- RPH3A | c.700C>T p.R234C (on ENST00000389385 / NM_001143854.2; = p.R230C on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs145114678; called by muse, mutect2, varscan2
- SAC3D1 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs370141149; called by muse, varscan2
- SAMD9 | c.4115T>C p.L1372P | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101180322; called by muse, mutect2, varscan2
- SCFD1 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100356484; called by muse, mutect2, varscan2
- SIGLEC9 | c.418A>T p.T140S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV99142900; called by muse, mutect2, varscan2
- SLC10A6 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs763476428, COSV56723519; called by muse, mutect2, varscan2
- SLC44A5 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs772124942, COSV100902301; called by mutect2, varscan2
- SLC6A14 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV100903186; called by muse, mutect2, varscan2
- SLFN11 | c.1776C>A p.N592K | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as COSV100390851; called by muse, mutect2, varscan2
- TMEM45B | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV99859471; called by muse, mutect2, varscan2
- TNFSF11 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 133/200 reads (67%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs760985300, COSV53478089; called by muse, mutect2, varscan2
- TNS1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs750425819, COSV50696322; called by muse, mutect2
- TSPYL1 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs754519261, COSV100889610; called by muse, mutect2, varscan2
- UBASH3A | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458099861, COSV99369793; called by muse, mutect2, varscan2
- ZBED2 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.21); catalogued as rs776334608, COSV99343282; called by muse, mutect2, varscan2
- UBR4 | c.12055A>C p.I4019L | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by mutect2, varscan2
- AC004922.1 | c.1110C>T p.S370= | Silent (SNP) | VAF 14/258 reads (5%) | catalogued as rs144704984; called by muse, mutect2
- C3 | c.3450G>A p.S1150= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs760685575, COSV99837035; called by muse, mutect2, varscan2
- CACNA1S | c.2901G>A p.E967= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs745738564, COSV100755204; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCR2 | c.675C>A p.I225= | Silent (SNP) | VAF 207/1691 reads (12%) | catalogued as COSV99432603; called by muse, mutect2, varscan2
- DHPS | c.687C>T p.I229= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs367826439; called by muse, mutect2, varscan2
- DNAH3 | c.9999G>A p.L3333= | Silent (SNP) | VAF 18/568 reads (3%) | catalogued as COSV99769292; called by muse, mutect2
- EGFLAM | c.2961T>C p.C987= (on ENST00000354891 / NM_001205301.2; = p.C979= on NM_152403.4) | Silent (SNP) | VAF 30/397 reads (8%) | called by mutect2, varscan2
- IFT27 | c.273G>T p.V91= (on ENST00000433985 / NM_001363003.2; = p.V90= on NM_006860.5) | Silent (SNP) | VAF 15/328 reads (5%) | catalogued as COSV100503597; called by muse, mutect2
- KYAT3 | c.36C>T p.S12= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs781324210, COSV53103372; called by muse, mutect2, varscan2
- MAB21L2 | c.81C>T p.I27= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV58261203; called by muse, mutect2
- MAN1C1 | c.1080C>T p.I360= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs749676923, COSV56046219; called by mutect2, varscan2
- MUC16 | c.43293C>A p.V14431= | Silent (SNP) | VAF 98/283 reads (35%) | catalogued as COSV101109993; called by muse, mutect2, varscan2
- MXRA5 | c.3702C>T p.H1234= | Silent (SNP) | VAF 135/695 reads (19%) | catalogued as rs763695097, COSV54241682, COSV99479770; called by muse, mutect2, varscan2
- PRDM9 | c.2601G>T p.R867= | Silent (SNP) | VAF 30/641 reads (5%) | catalogued as COSV57002630, COSV57007676; called by muse, mutect2
- RGS12 | c.687G>T p.A229= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100376053; called by muse, mutect2, varscan2
- WDR91 | c.498G>A p.L166= | Silent (SNP) | VAF 38/258 reads (15%) | catalogued as COSV100615784; called by muse, mutect2, varscan2
- ZNF713 | c.228A>G p.E76= (on ENST00000633730 / NM_001366796.2; = p.E89= on NM_182633.3) | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV101289519; called by muse, mutect2, varscan2
